Surgical pathology report (de-identified scan), TCGA case TCGA-D8-A1Y3, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D8-A1Y3-01A (Primary Tumor).

[page 1 of 2]
copy No.

Date:

Examination: Histopathological examination

Internal invoice No.

Cost of diagnostic procedure

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender: F

Material: **Multiple organ resection – right breast**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination: **up to 8 working days**

Clinical diagnosis:

14D-0-3
carcinoma, infiltrating duct. NOS 8500/3
Site: breast, NOS 850.9 dx 4/12/11

Examination performed on:

Macroscopic description:

Right breast sized 20 x 14 x 5 cm removed along with axillary tissues sized 10 x 5 x 3 cm and a skin flap of 18 x 10 cm. Tumour found in the upper outer quadrant, located 3 cm from the upper boundary, 1 cm from the base and 1.5 cm from the skin.

Microscopic description:

Carcinoma ductale invasivum NHG3 (3+3+3: 20 mitoses/10 HPF - visual area: 0.55mm).

Invasio carcinomatosa vasorum massiva.

Mamilla sine laesionibus.

Glandular tissue showing mastopathia fibrosa.

Axillary lymph nodes:

Metastases carcinomatosae in lymphonodis (No V / VIII).

Infiltratio telae perinodalis. Emboliae carcinomatosae vasorum.

Histopathological diagnosis:

Carcinoma ductale invasivum mammae dextrae. Invasive ductal carcinoma of the right breast

Metastases carcinomatosae in lymphonodis axillae (No V / VIII). Cancer metastases in axillary lymph nodes (No V/VIII)

.(NHG3, pT2, pN2a).

Invasio carcinomatosa vasorum massiva. Massive vascular invasion.

Compliance validated by:

Examination performed on:

Results of immunohistochemical examination:

Estrogen receptors found in over 75% of neoplastic cell nuclei. Progesterone receptors found in over 75% of neoplastic cell nuclei.

HER2 protein stained with Ventana's Pathway HER-2/neu (4B5) rabbit antibody. Score=2+, FISZ verification recommended.

Dual/Synchronous Primary, Noted		

[page 2 of 2]
Examination: Histopathological examination

Examination No.: (

Patient: XXX

PESEL: XXX

Gender: F

Examination performed on: :

Result of immunohistochemical examination:

RESULT OF HER2/neu GENE AMPLIFICATION with the FISH method by Path Vysion HER2 DNA Probe Kit

FINAL RESULT:

HER-2 GENE AMPLIFICATION NOT FOUND

Compliance validated by:

Supplementary information:

Size of the tumour 3.5 x 2.5 x 2.0 cm

Compliance validated by:

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file eb33e4a4-e3c7-4e5b-a065-45ab62e83ea2 (TCGA-D8-A1Y3.E8D4229D-5049-4991-BDE0-AFC2CBC1827E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).